MMRF case MMRF_1723 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/30738494-c141-4d90-801a-7fd2d70ae151

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.6 years (25,417 days); ISS stage: I; Days to last known disease status: 1,087 days (3.0 years); Days to last follow up: 1,087 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 267 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 128 days; Days to treatment end: 267 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 272 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -77 (ECOG 0): M Protein 1.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 163 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 24.9 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 3.07 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 5.83 mmol/L; C-Reactive Protein 0.01 mg/dL.
- Day 30 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 38.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 309 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7.1 g/dL; Glucose 13 mmol/L.
- Day 113 (ECOG 0): M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 7.13 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 6.38 mmol/L.
- Day 184 (ECOG 0): M Protein 0.57 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 8.16 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Glucose 5.94 mmol/L.
- Day 310: M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.4 mg/dL; Immunoglobulin G 7.19 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Glucose 11.4 mmol/L.
- Day 380 (ECOG 1): M Protein 0.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 6.72 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 5.06 mmol/L.
- Day 464 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 6.16 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Glucose 5.17 mmol/L.
- Day 548 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 5.99 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Glucose 5.78 mmol/L.
- Day 612 (ECOG 0): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 6.38 mmol/L.
- Day 730 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 5.03 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Glucose 9.63 mmol/L.
- Day 819 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 5.04 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 8.14 mmol/L.
- Day 933 (ECOG 0): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 6.21 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 5.61 mmol/L.
- Day 995 (ECOG 0): M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 6.63 g/L; Immunoglobulin A 1.57 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 7.87 mmol/L.
- Day 1,087: M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 7.03 g/L; Immunoglobulin A 1.93 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Glucose 7.04 mmol/L.

Other clinical attributes
- Day -77: Weight: 80 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1723_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -77 days.
- Sample MMRF_1723_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -77 days.
